Somatic mutation profile of tumor specimen TCGA-YL-A9WK-01A (aliquot TCGA-YL-A9WK-01A-11D-A377-08) from TCGA case TCGA-YL-A9WK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.7 years (23,272 days).
Specimen TCGA-YL-A9WK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab422c8-2264-4235-a205-c76144017ff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WK-10A (Blood Derived Normal), aliquot TCGA-YL-A9WK-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c9a0332-62d3-477c-946d-7cf1ce499112

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2065C>G p.R689G | Missense Mutation (SNP) | VAF 20/71 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899946, COSV104427918; called by muse, mutect2, varscan2
- TP53 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 15/20 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1179209740, COSV99899915; called by muse, mutect2, varscan2
- ADGRG6 | c.749T>G p.F250C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99748005; called by muse, mutect2, varscan2
- ANO6 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100263616; called by muse, mutect2
- ARHGAP33 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.859); catalogued as rs746094199, COSV50131205, COSV99139143; called by muse, mutect2, varscan2
- C2orf16 | c.41A>T p.Y14F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.131); catalogued as COSV101284407; called by muse, mutect2
- FAM111B | c.1679G>C p.G560A | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV100639331; called by muse, mutect2
- FMO3 | c.1390G>C p.G464R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs550307887, COSV100882519; called by muse, mutect2, varscan2
- HSD17B4 | c.1895C>T p.P632L (on ENST00000414835 / NM_001199291.3; = p.P607L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV99820019; called by muse, mutect2
- KANSL1 | c.2194A>G p.T732A | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1036089094, COSV99294737; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- KANSL1 | c.2192T>C p.L731P | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV99294738; called by muse, mutect2
- KCNQ5 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100572575; called by muse, mutect2, varscan2
- LAMA3 | c.8860C>T p.Q2954* (on ENST00000313654 / NM_198129.4; = p.Q1345* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99335426; called by muse, mutect2, varscan2
- MAPK8IP3 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as rs1361093977, COSV99169390; called by muse, mutect2, varscan2
- MYH11 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.414); catalogued as rs764831521, CM158366, COSV100259661; called by muse, mutect2, varscan2
- PCDHB6 | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV50714492, COSV99170544; called by muse, mutect2
- TMEM102 | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV99548435; called by muse, mutect2, varscan2
- USP53 | c.1809A>T p.R603S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV99917931; called by muse, mutect2, varscan2
- ZNF777 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99925271; called by muse, mutect2
- PCP2 | c.188_192del p.M63Kfs*16 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | called by mutect2, pindel, varscan2
- ACADVL | c.966G>A p.V322= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99138655; called by muse, mutect2
- ANKLE2 | c.2559G>T p.P853= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100785380, COSV63294616; called by muse, mutect2
- OR1N1 | c.837G>T p.V279= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as rs1275781874, COSV100509793; called by muse, mutect2, varscan2
- PCDHA5 | c.2154C>T p.T718= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs370219671; called by muse, mutect2, varscan2
- PCNT | c.1509G>A p.Q503= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100855801; called by muse, mutect2, varscan2
- SOX30 | c.594C>T p.G198= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV53937931; called by muse, mutect2, varscan2
- ZNF586 | c.129G>A p.V43= | Silent (SNP) | VAF 57/198 reads (29%) | catalogued as COSV101197709; called by muse, mutect2, varscan2
